Somatic mutation profile of tumor specimen 7069e990-4a4e-4984-a66d-4d835a (aliquot 7069e990-4a4e-4984-a66d-4d835a_D6) from CPTAC case 04OV057, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 7069e990-4a4e-4984-a66d-4d835a: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7d83e10-daba-4069-827f-1530bc366572.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen cced71f0-58dc-4e46-a02c-2af508 (Blood Derived Normal), aliquot cced71f0-58dc-4e46-a02c-2af508_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c1f9dae-2f1c-409a-8bb9-73071361d478

The open-access MAF lists 52 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Intron 3, Frame Shift Ins 1, RNA 1, 3'UTR 1, In Frame Del 1, Nonsense Mutation 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.1691A>G p.N564S | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs749742502; called by muse, mutect2
- ATP8B2 | c.1960G>A p.A654T (on ENST00000672630; = p.A621T on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.687); catalogued as rs748931644; called by muse, mutect2, varscan2
- C10orf90 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 84/384 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV99504962; called by muse, mutect2, varscan2
- CASKIN2 | c.2389C>G p.R797G | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58599540; called by muse, mutect2, varscan2
- CHFR | c.943G>A p.V315M (on ENST00000432561 / NM_001161345.1; = p.V274M on NM_018223.2) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771123706; called by muse, mutect2, varscan2
- DOCK1 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201574191; called by muse, mutect2, varscan2
- KCTD8 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs769382363, COSV63585801; called by muse, mutect2, varscan2
- LUZP4 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 106/324 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs201126715, COSV64218411; called by mutect2, varscan2
- MKI67 | c.8645C>T p.T2882M | Missense Mutation (SNP) | VAF 247/555 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs375655418; called by muse, mutect2
- OR8D1 | c.851T>G p.M284R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs367622301, COSV100766685; called by muse, mutect2, varscan2
- PPIP5K1 | c.3279C>G p.I1093M (on ENST00000396923; = p.I1068M on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV100613586; called by muse, mutect2, varscan2
- RTL3 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs760936695; called by muse, mutect2, varscan2
- SYDE1 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs567072793; called by muse, mutect2, varscan2
- ANKRD42 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CALML6 | c.343_350dup p.V118Hfs*22 | Frame Shift Ins (INS) | VAF 22/146 reads (15%) | called by mutect2, varscan2
- CCDC63 | c.297_299del p.L100del | In Frame Del (DEL) | VAF 11/97 reads (11%) | called by mutect2, pindel
- CCDC63 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- CEP170 | c.2111C>A p.A704E | Missense Mutation (SNP) | VAF 123/515 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CLCA1 | c.2023G>T p.V675L | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- GJA9 | c.1121A>T p.E374V | Missense Mutation (SNP) | VAF 113/387 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ICAM1 | c.1387C>A p.Q463K | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGSF8 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSYN2A | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 141/656 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MYOM1 | c.4168G>T p.V1390L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by mutect2, varscan2
- NCOA4 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PI4K2B | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RAD54B | c.1579A>G p.I527V | Missense Mutation (SNP) | VAF 63/437 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBM33 | c.2062C>A p.Q688K | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2
- RBPJL | c.1020+1G>C p.X340_splice | Splice Site (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- SDK2 | c.2252A>C p.N751T | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- SYCP1 | c.1365G>C p.K455N | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- THEM5 | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 146/528 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TSPYL2 | c.1643T>C p.F548S | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF572 | c.563A>T p.Y188F | Missense Mutation (SNP) | VAF 258/472 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.282); called by mutect2, varscan2
- GIPC2 | c.84C>A p.G28= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV54574575; called by muse, mutect2
- INTS3 | c.36A>G p.A12= | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2
- MIA | c.357C>G p.V119= | Silent (SNP) | VAF 58/127 reads (46%) | catalogued as COSV54571218; called by muse, mutect2, varscan2
- MRC1 | c.2457A>G p.E819= | Silent (SNP) | VAF 65/303 reads (21%) | called by muse, mutect2, varscan2
- MX1 | c.1236C>T p.H412= | Silent (SNP) | VAF 41/166 reads (25%) | called by muse, mutect2, varscan2
- NCOA6 | c.325C>A p.R109= | Silent (SNP) | VAF 54/200 reads (27%) | called by muse, mutect2, varscan2
- NOD1 | c.1374C>T p.D458= | Silent (SNP) | VAF 106/473 reads (22%) | catalogued as rs754763796; called by muse, mutect2, varscan2
- NPHP3 | c.1323T>C p.Y441= | Silent (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- POLD2 | c.174C>G p.L58= | Silent (SNP) | VAF 87/254 reads (34%) | called by muse, mutect2, varscan2
- RIN2 | c.915G>C p.T305= (on ENST00000255006 / NM_001242581.1; = p.T256= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/207 reads (25%) | called by muse, mutect2, varscan2
- SLC3A2 | c.744C>A p.L248= | Silent (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- SLFN12 | c.543C>T p.A181= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs1199208400, COSV59227912; called by muse, mutect2, varscan2
- FAM20C | c.864-17837T>C | Intron (SNP) | VAF 158/518 reads (31%) | called by muse, mutect2, varscan2
- FSHR | c.374+2558G>C | Intron (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- GGNBP1 | n.837C>T | RNA (SNP) | VAF 8/193 reads (4%) | catalogued as rs1336719093; called by muse, mutect2
- GH2 | c.457-92A>C | Intron (SNP) | VAF 101/275 reads (37%) | catalogued as rs545226470; called by muse, mutect2, varscan2
- IL10RA | c.*1578A>T | 3'UTR (SNP) | VAF 188/629 reads (30%) | called by muse, mutect2, varscan2
- TMEM170A | c.-36C>G | 5'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
